Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A7AQ, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A7AQ-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT PELVIC LYMPH NODES:
Seven lymph nodes, no tumor present. (0/7)
(B) LEFT PELVIC LYMPH NODES:
Four lymph nodes, no tumor present. (0/4)
(C) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

C&CF ICD-3
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
JW 8/22/13

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) RIGHT PELVIC LYMPH NODES – Consists of a single yellow-red fragment of fibroadipose tissue (8 x 4 x 1 cm). Sectioning reveals seven possible lymph nodes, ranging in size from 0.2 cm to 3.3 cm in greatest dimension. All lymph node candidates are entirely submitted.

SECTION CODE: A1, four lymph node candidates; A2, one lymph node candidate; A3, one lymph node candidate; A4, A5, one lymph node candidate, bisected.

(B) LEFT PELVIC LYMPH NODES – Consists of a single yellow-red fragment of fibroadipose tissue (7 x 4 x 0.8 cm). Sectioning reveals five possible lymph nodes ranging in size from 0.5 to 5 cm in greatest dimension. All lymph node candidates are entirely submitted.

SECTION CODE: B1, three lymph node candidates; B2, one lymph node candidate; B3, B4, one lymph node candidate, serially sectioned

(C) PROSTATE AND SEMINAL VESICLES – Supplemental report to follow.

CLINICAL HISTORY

None given.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

- (C) PROSTATE AND SEMINAL VESICLES:
PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (4+3) WITH TERTIARY GLEASON GRADE 5 COMPONENT
(SEE COMMENT).
TUMOR CONFINED TO THE PROSTATE.
Margins of resection free of tumor.
Right and left seminal vesicles, no tumor present.
Segments of right and left vasa deferentia, no tumor present.
PERINEURAL INVASION PRESENT.
No lymphovascular invasion identified.
PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE.

COMMENT

The prostate gland contains four foci of prostatic adenocarcinoma, two in the peripheral zone and two in the transition zone. The dominant tumor focus is located in the right lateral, right posterolateral, right posterior, mid posterior and left posterior peripheral zone. This tumor focus measures 1.4 x 0.5 cm in the largest cross-sectional dimension and it is present in the first two cross sections of the prostate and extensively in the apical region. This tumor focus exhibits predominantly Gleason grades 4 and 3. A minor component of Gleason grade 5 is present. This tumor exhibits an extensive cribriform pattern and also intraductal spread. The presence of intraductal spread is confirmed by a stain for basal cell markers and racemase (PIN 3). The second tumor focus is located in the left and right transition zone. This tumor focus measures 1.1 x 0.3 cm in the largest cross-sectional dimension and it is present in two cross sections, and focally in the base region. The third tumor focus is located in the right anterolateral and right lateral peripheral zone. This tumor focus measures 1.0 x 0.1 cm in the largest cross-sectional dimension and it is present in one cross section. The fourth tumor focus is located in the right transition zone. This tumor focus measures less than 0.2 x 0.1 cm in the largest cross-sectional dimension, and it is present in the first cross section and focally in the apical region. All tumor foci are confined to the prostate. The margins of resection are free of tumor. Immunostaining.

GROSS DESCRIPTION

(C) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (4.7 x 3.8 x 3.5 cm, 48 grams, post-fixation) has the usual shape. The soft tissue present along the posterolateral aspects of the prostate is scant and symmetrical. A nodule is palpated in the right apex. Serial cross sections after fixation demonstrate a firm area consistent with tumor in the right side of the first cross section of the prostate.

[page 3 of 3]
Specimen Date/Time:

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: C1-C4, right seminal vesicle and segment of right vas deferens from the base towards the tip; C5-C8, left seminal vesicle and segment of left vas deferens from the base towards the tip; C9, flap over posterior surface; C10, C11, prostatic base, right border; C12-C14, prostatic base, right posterior border; C15-C23, prostatic base, central portion; C24, C25, prostatic base, left border; C26-C28, prostatic base, left posterior border; C29, apex anterior; C30, C31, apex left; C32, C33, apex posterior; C34, apex right; C35, detached portions of margin of resection according to the specimen radiograph; C36-C51, sections of the four cross sections of the prostate according to the specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black.

Blue ink (C9, 12-14, 38, 42, 46 and 50) and orange ink (C42, 43, 46, 47, 50 and 51) denote surfaces that do not represent the true margin of resection.

SNOMED CODES

Entire report and diagnosis completed by:

-----END OF REPORT-----

ICDPA Discrepancy		/

Source: NCI Genomic Data Commons file 38d02cbc-8173-4854-a584-58bfc0a22570 (TCGA-KK-A7AQ.D507BEE9-3883-4008-B07C-7F257C40AFF6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).